Somatic mutation profile of tumor specimen TCGA-06-A6S0-01A (aliquot TCGA-06-A6S0-01A-11D-A33T-08) from TCGA case TCGA-06-A6S0, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 79.5 years (29,037 days).
Specimen TCGA-06-A6S0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8725ba77-fa5e-4341-96e6-b50e95c238b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-A6S0-10A (Blood Derived Normal), aliquot TCGA-06-A6S0-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d260c80-8a19-4d48-8ee1-6a4fb233d3bf

The open-access MAF lists 66 somatic variants for this specimen: 40 protein-altering or splice-affecting, 21 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 21, Frame Shift Del 3, Intron 2, RNA 2, 5'UTR 1, Nonsense Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL5 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374627579; called by muse, mutect2, varscan2
- ADCY5 | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs1386912280, COSV100568169; called by muse, mutect2, varscan2
- ADGRL4 | c.396del p.I133Sfs*4 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as COSV66061364; called by mutect2, pindel, varscan2
- ARAP3 | c.665G>A p.S222N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs574149716, COSV99500195; called by muse, mutect2, varscan2
- BRD4 | c.1922A>C p.E641A | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99651309; called by muse, mutect2, varscan2
- CACNA2D3 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 11/18 reads (61%) | catalogued as rs1417940298, COSV55537866; called by muse, mutect2, varscan2
- CENPJ | c.3068G>A p.R1023H | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs146950242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHAT | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM055128, COSV60322745, COSV60334430; called by muse, mutect2, varscan2
- CHRNA4 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.698); catalogued as rs762764855, COSV64719396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL2A1 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1064796856, COSV61530023; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.5168C>G p.P1723R | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99453276; called by muse, mutect2, varscan2
- DNMT3B | c.204+1G>A p.X68_splice | Splice Site (SNP) | VAF 22/45 reads (49%) | catalogued as COSV52418030; called by muse, mutect2, varscan2
- FBLN5 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as rs540001032, COSV99969877; called by muse, mutect2, varscan2
- FDPS | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100756271; called by muse, mutect2, varscan2
- GTPBP6 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs773299422, COSV100397817; called by muse, mutect2, varscan2
- ICAM4 | c.625A>T p.I209F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV99321092; called by muse, mutect2, varscan2
- IGHV3-66 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.155); catalogued as rs562734265; called by muse, mutect2, varscan2
- IGKV1-12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs764773736; called by muse, mutect2
- JPH1 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs746817547, COSV100646749; called by muse, mutect2, varscan2
- KRT73 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1045971477, COSV99988806; called by muse, mutect2, varscan2
- L3MBTL4 | c.962T>C p.V321A | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV99530760; called by muse, mutect2, varscan2
- MAPK10 | c.290C>T p.T97M (on ENST00000359221 / NM_001351625.2; = p.T135M on NM_002753.5) | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs138883015; called by muse, mutect2, varscan2
- MIER1 | c.1085G>A p.R362H (on ENST00000355356 / NM_001077701.3; = p.R379H on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs764657305, COSV100591238; called by muse, varscan2
- NTSR1 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1208532915, COSV65138047; called by muse, mutect2, varscan2
- PCDHGA6 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as rs974732178, COSV99545373; called by muse, mutect2, varscan2
- SCN8A | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs751743305, COSV100634170; called by muse, varscan2
- SIGLEC10 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV100219378; called by muse, mutect2, varscan2
- SLC22A8 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.223); catalogued as rs374308646; called by muse, mutect2, varscan2
- SLC26A3 | c.2050G>A p.V684I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs199895223, COSV100385272; called by muse, mutect2, varscan2
- SLC2A14 | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV100533979; called by muse, mutect2, varscan2
- SLCO2B1 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99215091; called by muse, mutect2, varscan2
- TFAP2D | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50411015, COSV99147218; called by muse, mutect2, varscan2
- TFAP2D | c.1094C>A p.T365N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.055); catalogued as COSV99147226; called by muse, mutect2, varscan2
- TPO | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61111439; called by muse, mutect2, varscan2
- UBTF | c.500G>T p.R167I | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV100256107; called by muse, mutect2
- ZNF609 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs752575621, COSV58584905; called by muse, mutect2, varscan2
- ARHGEF5 | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by mutect2, varscan2
- PIK3CA | c.1364_1390del p.L455_G463del | In Frame Del (DEL) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- RB1CC1 | c.3641_3644del p.K1214Tfs*16 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | called by mutect2, pindel, varscan2
- UNC79 | c.2535del p.S846Pfs*33 (on ENST00000393151 / NM_001346218.2; = p.S669Pfs*33 on NM_020818.5) | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | called by mutect2, pindel, varscan2
- APBA3 | c.1377G>A p.A459= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs935046625, COSV53665630; called by muse, mutect2, varscan2
- CCT8L2 | c.591C>T p.S197= | Silent (SNP) | VAF 50/107 reads (47%) | catalogued as rs534377200, COSV63462073; called by muse, mutect2, varscan2
- CHRNB1 | c.522C>T p.Y174= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs774012484, COSV99548492; called by muse, mutect2, varscan2
- COBL | c.2931A>G p.S977= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99473910; called by muse, mutect2, varscan2
- DEFB113 | c.132G>A p.P44= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs752895772, COSV59038232; called by muse, mutect2, varscan2
- ECI2 | c.270G>A p.K90= (on ENST00000380118 / NM_206836.3; = p.K60= on NM_006117.2) | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as rs1319785244, COSV100326732; called by muse, mutect2, varscan2
- FBN1 | c.4317T>G p.A1439= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV100356217; called by muse, mutect2, varscan2
- FER1L6 | c.795C>T p.N265= | Silent (SNP) | VAF 52/136 reads (38%) | catalogued as rs748228872, COSV101205820; called by muse, mutect2, varscan2
- FLG2 | c.6147C>T p.H2049= | Silent (SNP) | VAF 179/394 reads (45%) | catalogued as rs146074268; called by muse, mutect2, varscan2
- KIF20A | c.33C>A p.G11= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99137511; called by muse, mutect2, varscan2
- LAMB1 | c.3825T>C p.T1275= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as COSV99741554; called by muse, mutect2, varscan2
- LHCGR | c.669G>A p.G223= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV54304597, COSV99684128; called by muse, mutect2, varscan2
- LRP2 | c.3447C>T p.C1149= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV99789964; called by muse, mutect2, varscan2
- NEB | c.10833C>T p.D3611= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as rs376268872; called by muse, mutect2, varscan2
- NPBWR1 | c.774G>A p.A258= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1163156562, COSV58695549; called by muse, mutect2, varscan2
- RHAG | c.1153T>C p.L385= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100006830; called by muse, mutect2, varscan2
- SDK1 | c.5865G>A p.P1955= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as rs144472783; called by muse, mutect2, varscan2
- SLC17A3 | c.147T>C p.N49= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100399374; called by muse, mutect2, varscan2
- SRD5A2 | c.561G>A p.T187= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs369072138; called by mutect2, varscan2
- UTP6 | c.1749G>A p.E583= | Silent (SNP) | VAF 52/148 reads (35%) | catalogued as COSV99912096; called by muse, mutect2, varscan2
- ZNF831 | c.3264G>A p.R1088= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs1432078773, COSV100926214; called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1916C>A | Intron (SNP) | VAF 47/126 reads (37%) | catalogued as COSV51642246, COSV99151326; called by muse, mutect2, varscan2
- HERC2P3 | n.294C>T | RNA (SNP) | VAF 4/21 reads (19%) | catalogued as rs748658535; called by mutect2, varscan2
- PDE4D | c.455+124680G>A | Intron (SNP) | VAF 50/128 reads (39%) | catalogued as COSV100508744; called by muse, mutect2, varscan2
- SCN2A | c.-1_1del | 5'UTR (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- SPATA8 | n.225G>A | RNA (SNP) | VAF 13/39 reads (33%) | catalogued as rs1244061590, COSV100139087; called by muse, mutect2, varscan2
